Somatic mutation profile of tumor specimen TCGA-FI-A2EY-01A (aliquot TCGA-FI-A2EY-01A-12D-A18P-09) from TCGA case TCGA-FI-A2EY, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 63.1 years (23,042 days).
Specimen TCGA-FI-A2EY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d54adcbc-a6b9-4675-8b55-ad6465b8b8ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FI-A2EY-10A (Blood Derived Normal), aliquot TCGA-FI-A2EY-10A-01D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8fc4eb1-c10b-4fb9-bf62-2dfb780468f8

The open-access MAF lists 103 somatic variants for this specimen: 81 protein-altering or splice-affecting, 17 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 17, Nonsense Mutation 5, Frame Shift Del 4, In Frame Del 3, 5'UTR 2, RNA 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 23/75 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 61/68 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASDHPPT | c.190C>G p.R64G | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99593358; called by muse, mutect2, varscan2
- ABCA12 | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV99790785; called by muse, mutect2, varscan2
- ACTRT2 | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs549750914, COSV101007637; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3817G>C p.V1273L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV99719797; called by muse, varscan2
- AIMP2 | c.570G>C p.K190N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99552094; called by muse, mutect2, varscan2
- ARHGAP17 | c.2621A>G p.N874S (on ENST00000289968 / NM_001006634.3; = p.N796S on NM_018054.6) | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); catalogued as rs759941236, COSV99253690; called by muse, mutect2, varscan2
- ARHGAP35 | c.4012C>T p.Q1338* | Nonsense Mutation (SNP) | VAF 50/99 reads (51%) | catalogued as COSV101351294; called by muse, mutect2, varscan2
- ASAH1 | c.179G>C p.R60T | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV100025842; called by muse, mutect2, varscan2
- ATP13A5 | c.1664G>C p.G555A | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.186); catalogued as COSV100665376; called by muse, mutect2, varscan2
- BCL9 | c.3784C>G p.Q1262E | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.191); catalogued as rs782777919, COSV99325441; called by muse, mutect2, varscan2
- BTBD11 | c.2624C>T p.A875V (on ENST00000280758 / NM_001018072.2; = p.A412V on NM_001017523.2) | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.033); catalogued as rs757334427, COSV99776284; called by muse, mutect2, varscan2
- C12orf54 | c.27G>T p.Q9H | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); catalogued as COSV100011634; called by muse, mutect2, varscan2
- CCNT1 | c.350C>G p.S117C | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV56063688, COSV99980820; called by muse, mutect2, varscan2
- CD22 | c.2468C>T p.S823L | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs765135715, COSV99323438; called by muse, mutect2, varscan2
- CEMIP | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1234631188, COSV54988324; called by muse, mutect2, varscan2
- CEP97 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV100511948; called by muse, mutect2, varscan2
- CFAP45 | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV100928624; called by muse, mutect2
- CNOT3 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55360199; called by muse, mutect2, varscan2
- CNTF | c.500A>G p.Q167R | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100284579; called by muse, mutect2, varscan2
- CNTNAP4 | c.3526G>A p.V1176M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as rs773791364, COSV100272214; called by muse, mutect2, varscan2
- COL4A4 | c.4369G>C p.G1457R | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs746683977, COSV61636900; called by muse, mutect2, varscan2
- DECR2 | c.172G>C p.A58P | Missense Mutation (SNP) | VAF 82/231 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV99557219; called by muse, mutect2, varscan2
- DIP2C | c.3892G>A p.G1298S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.954); catalogued as rs765021803, COSV99792557; called by muse, mutect2, varscan2
- DISC1 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as COSV100790497; called by muse, mutect2, varscan2
- DOCK7 | c.3343G>T p.V1115L (on ENST00000635253 / NM_001367561.1; = p.V1084L on NM_033407.3) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99225014; called by muse, mutect2, varscan2
- DOK6 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.265); catalogued as rs779144654, COSV66927031; called by muse, mutect2, varscan2
- DUSP22 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 31/135 reads (23%) | catalogued as COSV100739893; called by muse, mutect2, varscan2
- EIF2AK3 | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100303909, COSV57548521; called by muse, mutect2, varscan2
- ELP1 | c.3733C>G p.L1245V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101010435; called by muse, mutect2, varscan2
- FAF1 | c.1874C>T p.T625I | Missense Mutation (SNP) | VAF 44/49 reads (90%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV100875829; called by muse, mutect2, varscan2
- FAM135A | c.836T>C p.V279A (on ENST00000370479 / NM_001351599.1; = p.V262A on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV99526125; called by muse, mutect2, varscan2
- FAM228A | c.225_227del p.R76del | In Frame Del (DEL) | VAF 8/57 reads (14%) | catalogued as rs751237028; called by pindel, varscan2
- FDCSP | c.188G>T p.W63L | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.369); catalogued as COSV100525804, COSV100525808; called by muse, mutect2, varscan2
- GSTA5 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 97/147 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV99489636; called by muse, mutect2, varscan2
- GYS1 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.129); catalogued as rs962330001, COSV99620909; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INPP5F | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV100740242; called by muse, mutect2, varscan2
- INPP5J | c.2279G>A p.R760H (on ENST00000331075 / NM_001284285.2; = p.R392H on NM_001002837.2) | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs199693963; called by muse, mutect2, varscan2
- LNPEP | c.2872C>G p.L958V | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV99183562; called by muse, mutect2, varscan2
- MAP3K11 | c.1756G>T p.D586Y | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV100482615; called by muse, mutect2, varscan2
- MAP3K12 | c.1189A>G p.I397V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV99913370; called by muse, mutect2, varscan2
- MAP4 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64243583; called by muse, mutect2, varscan2
- MDN1 | c.14767G>A p.E4923K | Missense Mutation (SNP) | VAF 79/112 reads (71%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV101021544; called by muse, mutect2, varscan2
- MPEG1 | c.377A>G p.N126S | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs943867387, COSV99915622; called by muse, mutect2, varscan2
- MUC4 | c.14482G>A p.E4828K (on ENST00000463781 / NM_018406.7; = p.E592K on NM_004532.6) | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.515); catalogued as rs527606179, COSV100203528; called by muse, mutect2, varscan2
- MYT1L | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV67729755; called by muse, mutect2, varscan2
- NARS2 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748157459, COSV99807327; called by muse, mutect2
- NCOA3 | c.1184A>T p.N395I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100507792; called by muse, mutect2, varscan2
- OR11H12 | c.317A>T p.N106I | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV101612508, COSV73569193, COSV73569328; called by mutect2, varscan2
- PCNX3 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.829); catalogued as COSV100482616; called by muse, mutect2, varscan2
- PKD2L2 | c.1230T>A p.F410L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99296484; called by muse, mutect2, varscan2
- PPP4R3A | c.1669C>T p.R557C (on ENST00000554943 / NM_001366432.1; = p.R544C on NM_001284280.1) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100466218; called by muse, mutect2, varscan2
- RGS6 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV59567535; called by muse, mutect2, varscan2
- RSPO3 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143484700; called by muse, mutect2, varscan2
- SEMA4D | c.1198A>G p.M400V | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100358548; called by muse, mutect2, varscan2
- SLC5A7 | c.1614A>T p.K538N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as COSV50896379; called by muse, mutect2, varscan2
- SOGA1 | c.2715C>G p.F905L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.044); catalogued as COSV52917475; called by muse, mutect2, varscan2
- SPTAN1 | c.3917C>G p.S1306* | Nonsense Mutation (SNP) | VAF 9/16 reads (56%) | catalogued as COSV100823759; called by muse, mutect2, varscan2
- SSTR5 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs573226759, COSV53511509; called by muse, mutect2, varscan2
- SYNE4 | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.196); catalogued as COSV99431182; called by muse, mutect2, varscan2
- THAP7 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.362); catalogued as COSV53147905; called by muse, mutect2, varscan2
- TIGD3 | c.1318A>G p.T440A | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV99361787; called by muse, mutect2, varscan2
- TINAG | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs376779713, COSV52513828; called by muse, mutect2, varscan2
- TUBGCP6 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as rs757545083, COSV99955882; called by muse, mutect2, varscan2
- UHMK1 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs767864729, COSV99966297; called by muse, mutect2, varscan2
- ULK1 | c.1969C>T p.R657* | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | catalogued as rs373878374, COSV58855019; called by muse, mutect2, varscan2
- URGCP | c.1273G>A p.D425N (on ENST00000453200 / NM_001077663.3; = p.D416N on NM_017920.4) | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs564610799, COSV56244750; called by muse, mutect2, varscan2
- USP32 | c.3680G>A p.R1227Q | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.435); catalogued as rs571832352, COSV100342325; called by muse, mutect2, varscan2
- XIRP2 | c.2657C>A p.T886N (on ENST00000628543; = p.T1061N on NM_152381.6) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99744840; called by muse, mutect2, varscan2
- ZDBF2 | c.5920C>T p.R1974C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs375685194; called by muse, varscan2
- ZKSCAN2 | c.1856G>A p.W619* | Nonsense Mutation (SNP) | VAF 43/127 reads (34%) | catalogued as COSV60158811; called by muse, mutect2, varscan2
- ZNF343 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs745831638, COSV99601501; called by muse, mutect2, varscan2
- ZNF385A | c.449C>A p.A150D (on ENST00000338010 / NM_001130967.3; = p.A130D on NM_015481.3) | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.572); catalogued as COSV100566933; called by muse, mutect2, varscan2
- ZNF554 | c.813A>C p.R271S | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.5); catalogued as COSV100421245; called by muse, mutect2, varscan2
- ALPI | c.867_875del p.E289_G291del | In Frame Del (DEL) | VAF 19/105 reads (18%) | called by mutect2, pindel, varscan2
- BAK1 | c.121del p.Y41Tfs*107 | Frame Shift Del (DEL) | VAF 19/88 reads (22%) | called by mutect2, varscan2
- MTERF2 | c.698_699del p.F233Sfs*10 | Frame Shift Del (DEL) | VAF 31/43 reads (72%) | called by mutect2, pindel, varscan2
- NKAPL | c.1147_1175del p.K383Afs*9 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel
- RUBCN | c.1327_1336delinsT p.S443_S446delinsC | In Frame Del (DEL) | VAF 28/69 reads (41%) | called by pindel, varscan2*
- ZNF613 | c.1362del p.F456Lfs*86 (on ENST00000293471 / NM_001031721.4; = p.F420Lfs*86 on NM_024840.4) | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | called by mutect2, pindel, varscan2
- ARHGEF17 | c.921G>A p.R307= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV99736068; called by muse, mutect2, varscan2
- BRF1 | c.783G>A p.R261= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as rs143363988; called by muse, mutect2, varscan2
- C2CD6 | c.102C>G p.P34= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as COSV99633654; called by muse, mutect2, varscan2
- CHRD | c.549G>A p.A183= | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as rs769854267, COSV52613317; called by muse, mutect2, varscan2
- EIF2AK1 | c.1614A>C p.T538= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99552095; called by muse, mutect2, varscan2
- EVC2 | c.795C>T p.L265= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs1275549226, COSV100186313; called by muse, mutect2, varscan2
- FAM135B | c.2970C>A p.T990= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs781105888, COSV99425406, COSV99427374; called by muse, mutect2, varscan2
- GIMAP4 | c.822G>A p.K274= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99750487, COSV99750825; called by muse, mutect2, varscan2
- KIR2DL1 | c.708C>T p.S236= | Silent (SNP) | VAF 30/298 reads (10%) | catalogued as rs1370770277; called by mutect2, varscan2
- KSR2 | c.555G>A p.P185= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs373628463; called by muse, mutect2, varscan2
- MYH7 | c.3261G>C p.L1087= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100805848, COSV100806288; called by muse, mutect2, varscan2
- MYH9 | c.2571C>T p.V857= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs771942552, COSV99339275; called by muse, mutect2, varscan2
- PKP1 | c.1509C>T p.N503= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs146580475; called by muse, mutect2, varscan2
- RPL6 | c.573G>A p.Q191= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99176149; called by muse, mutect2, varscan2
- SBK2 | c.30G>A p.P10= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as rs369991451; called by muse, mutect2, varscan2
- SEMA3F | c.1290G>A p.E430= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs749691069, COSV99137639; called by muse, mutect2, varscan2
- ZNF418 | c.1356G>A p.R452= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV68676246; called by muse, mutect2, varscan2
- C14orf177 | n.589C>T | RNA (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100362715; called by muse, mutect2, varscan2
- KRT8 | c.-13_-2del | 5'UTR (DEL) | VAF 23/75 reads (31%) | catalogued as rs764376392; called by mutect2, pindel, varscan2
- LRP5L | n.342T>C | RNA (SNP) | VAF 26/109 reads (24%) | catalogued as COSV101292801; called by muse, mutect2, varscan2
- MAP3K20 | c.987+4019T>C | Intron (SNP) | VAF 17/65 reads (26%) | catalogued as rs201188933, COSV100169257; called by muse, mutect2, varscan2
- ZNF839 | c.-10G>C | 5'UTR (SNP) | VAF 90/384 reads (23%) | catalogued as COSV99216320; called by muse, mutect2, varscan2
